Gene-level copy-number profile of tumor specimen ALCH-B2T3-TTP1-B from ALCHEMIST case ALCH-B2T3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.1 years (26,350 days).
Specimen ALCH-B2T3-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7399887b-ae7b-4ae3-be3c-fdaedf9315f1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2T3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/e7ac3537-2b1d-40c8-97e4-e47b127c1600

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 10,791; copy number 2: 46,768; copy number 3: 926; copy number 4: 49; copy number 5: 109; copy number 6: 26; copy number 7: 73; copy number 8: 5; copy number 10: 23; copy number 12: 12; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,872,463–89,872,702, 1 gene: IGKV2D-38.
- chr2:89,947,512–89,990,221, 5 genes: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:90,100,236–90,100,738, 1 gene: IGKV1D-16.
- chr2:91,684,447–91,685,884, 1 gene: DRD5P1.
- chr11:1,828,307–1,841,680, 2 genes: SYT8, TNNI2.
- chr11:2,159,779–2,173,138, 3 genes (within-gene range 0–2): INS, TH, MIR4686.
- chr15:25,191,416–25,204,438, 8 genes (within-gene range 0–2): SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19.
- chr17:18,951,625–18,954,149, 1 gene (within-gene range 0–1): AC090286.1.
- chr19:42,866,464–42,879,822, 1 gene: PSG1.
- chr19:42,949,503–42,950,387, 1 gene (within-gene range 0–1): CEACAMP7.
- chr19:43,064,209–43,083,045, 1 gene (within-gene range 0–1): PSG2.
- chr19:43,192,702–43,248,646, 2 genes (within-gene range 0–2): PSG4, CEACAMP10.
- chr19:50,882,096–50,896,398, 1 gene: KLKP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 249 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,004,797–90,005,629, 1 gene, copy number 5: IGKV2D-24.
- chr10:45,812,648–46,537,864, 22 genes, copy number 6: AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P, ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.
- chr12:53,251,251–53,254,406, 1 gene, copy number 6: MFSD5.
- chr12:56,822,985–60,269,686, 98 genes, copy number 5–7 (broad region; genes not listed).
- chr12:64,186,316–66,170,072, 58 genes, copy number 5–7: C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr12:68,805,011–71,441,898, 49 genes, copy number 7–12 (within-gene range 4–12): AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8.
- chr12:91,871,122–92,531,324, 16 genes, copy number 5: AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1.
- chr16:90,102,271–90,178,344, 1 gene, copy number 6 (within-gene range 1–6): FAM157C.
- chr16:90,110,574–90,222,851, 3 genes, copy number 6–19 (within-gene range 3–19): AC133919.2, RNU6-355P, LINC02193.

Autosomal genes at a single copy (total copy number 1): 8,188. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
